Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A42Y, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A42Y-01A (Primary Tumor).

Reviewer	Data Reviewed: 8/17/12	

Procurement Date: Laterality: Malignant melanoma

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, hand *NON-glucanous, per TSS*

Tumor size: 4 x 3 x 3 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 0/10 positive for metastasis (Axillary 0/10)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow depth 5mm

Comments: Clark level not specified

ICD-03

melanoma, Nos

8720/3

Site: skin, hand

C44.6

8-3-12

RD

Source: NCI Genomic Data Commons file 3911bc9f-e4f1-488b-b8b6-833bff1865e8 (TCGA-EB-A42Y.B7081129-C993-4046-829F-4CECF0DCB12E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).